Somatic mutation profile of tumor specimen C3L-08259-01 (aliquot CPT0477490008) from CPTAC case C3L-08259, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 44.1 years (16,119 days).
Specimen C3L-08259-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f8bcc4c-ae9b-4c4d-aa58-4dda5419e701.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08259-31 (Blood Derived Normal), aliquot CPT0475650001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf15bbb5-08d2-4083-b1ca-2db6f4cb8868

The open-access MAF lists 869 somatic variants for this specimen: 552 protein-altering or splice-affecting, 290 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 514, Silent 290, Nonsense Mutation 25, Intron 14, Splice Region 8, 3'UTR 6, Frame Shift Del 3, 5'UTR 3, 3'Flank 2, RNA 2, In Frame Del 1, Splice Site 1.

Variants (750 of 869; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJA8 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 162/552 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs45619342, CM081297, COSV53790822; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 96/438 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 83/382 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen possibly damaging (0.664); catalogued as rs147148566, COSV53202265, COSV53220854; called by muse, mutect2, varscan2
- ABCC12 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1443811047; called by muse, mutect2, varscan2
- AC100868.1 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 84/470 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.18); catalogued as rs1181774927, COSV51842383; called by muse, mutect2, varscan2
- ADAM12 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200464679, COSV64102697; called by muse, mutect2, varscan2
- ADAM28 | c.228G>A p.K76= | Splice Region (SNP) | VAF 55/271 reads (20%) | catalogued as COSV56098833; called by muse, mutect2, varscan2
- ADAMTS19 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV50786744; called by muse, mutect2, varscan2
- ADGRL2 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV54656616; called by muse, mutect2, varscan2
- AFF1 | c.3190C>T p.R1064C | Missense Mutation (SNP) | VAF 63/306 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867215989, COSV57119983; called by muse, mutect2, varscan2
- ALS2 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 94/331 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51883609, COSV51885889; called by muse, mutect2, varscan2
- ANK3 | c.7729G>A p.V2577M | Missense Mutation (SNP) | VAF 127/504 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1420884936; called by muse, mutect2, varscan2
- ANKRD11 | c.6005C>T p.S2002F | Missense Mutation (SNP) | VAF 154/739 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV99039934; called by muse, mutect2, varscan2
- ANKRD12 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as rs777352553; called by muse, mutect2, varscan2
- APOB | c.12674G>A p.G4225E | Missense Mutation (SNP) | VAF 95/390 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as rs1558559061, COSV51939023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP15 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54493223; called by muse, mutect2
- ARHGEF19 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 166/724 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1180461326, COSV54616300; called by muse, mutect2, varscan2
- ARHGEF5 | c.3155-1G>A p.X1052_splice | Splice Site (SNP) | VAF 36/550 reads (7%) | catalogued as COSV50210851; called by muse, mutect2
- ARID1B | c.6607C>T p.L2203F | Missense Mutation (SNP) | VAF 141/543 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV51656652; called by muse, mutect2, varscan2
- ASTN1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 140/650 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs145957941, COSV56082361; called by muse, mutect2, varscan2
- B3GNT3 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 110/435 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200934033; called by muse, mutect2, varscan2
- BCL9L | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 151/518 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV52682195; called by muse, mutect2, varscan2
- BDNF | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 82/409 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1349681470, COSV59233092, COSV59234846; called by muse, mutect2, varscan2
- BICC1 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 120/544 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54067470; called by muse, mutect2, varscan2
- BMPER | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 120/676 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as rs139762183, COSV51810723; called by muse, mutect2, varscan2
- BPIFB6 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 83/315 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV62754076; called by muse, mutect2, varscan2
- BRINP1 | c.2047G>A p.G683S | Missense Mutation (SNP) | VAF 111/475 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56294551; called by muse, mutect2, varscan2
- BTNL9 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 87/389 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs1364639951; called by muse, mutect2, varscan2
- C12orf56 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 100/323 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1447504957; called by muse, mutect2, varscan2
- C1orf127 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs1361887084; called by muse, mutect2, varscan2
- C1orf158 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 121/477 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.12); catalogued as COSV55347520; called by muse, mutect2, varscan2
- C8orf34 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100298536, COSV57402297; called by muse, mutect2, varscan2
- C8orf34 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748608422, COSV57412574; called by muse, mutect2, varscan2
- CACNG3 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV50069569; called by muse, mutect2, varscan2
- CADPS2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100465351; called by muse, mutect2, varscan2
- CALCA | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 126/489 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100523994; called by muse, mutect2, varscan2
- CAMSAP3 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 118/477 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs747388400, COSV50330767; called by muse, mutect2, varscan2
- CARD11 | c.3144G>A p.K1048= | Splice Region (SNP) | VAF 69/343 reads (20%) | catalogued as rs1364217328; called by muse, mutect2, varscan2
- CASS4 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 101/474 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754417275; called by muse, mutect2, varscan2
- CCDC150 | c.3238C>T p.R1080* | Nonsense Mutation (SNP) | VAF 88/366 reads (24%) | catalogued as rs747585654, COSV55874080; called by muse, mutect2, varscan2
- CCDC166 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 32/791 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs1554616999; called by muse, mutect2
- CCDC3 | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 84/405 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.592); catalogued as rs774014876; called by muse, mutect2
- CCDC40 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 107/500 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.636); catalogued as rs775425348, COSV66474090; called by muse, mutect2, varscan2
- CCDC62 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV53436267; called by muse, mutect2
- CD1C | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 81/387 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs911889067; called by muse, mutect2, varscan2
- CD300A | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 104/432 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as rs267605039, COSV60410152; called by muse, varscan2
- CDH7 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 104/387 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59880968; called by muse, mutect2, varscan2
- CDS1 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs150621905; called by muse, mutect2, varscan2
- CELSR1 | c.4450C>T p.R1484C | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53099246; called by muse, mutect2, varscan2
- CH25H | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 120/499 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV64092241; called by muse, mutect2, varscan2
- CHAF1A | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 105/533 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV56671655; called by muse, mutect2, varscan2
- CHL1 | c.2071G>A p.E691K (on ENST00000397491 / NM_001253387.1; = p.E707K on NM_006614.4) | Missense Mutation (SNP) | VAF 89/382 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.12); catalogued as rs771423332, COSV56593907; called by muse, mutect2, varscan2
- CLIP2 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 208/586 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs781915980; called by muse, varscan2
- COBLL1 | c.1406C>T p.S469F (on ENST00000392717; = p.S431F on NM_014900.5) | Missense Mutation (SNP) | VAF 75/381 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1217626367; called by muse, mutect2, varscan2
- COL3A1 | c.2797G>A p.G933R | Missense Mutation (SNP) | VAF 89/432 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM119026, COSV58598341; called by muse, mutect2, varscan2
- COL4A6 | c.4498G>A p.G1500R | Missense Mutation (SNP) | VAF 122/254 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459471740, COSV57864588; called by muse, mutect2, varscan2
- COL7A1 | c.5702G>A p.G1901D | Missense Mutation (SNP) | VAF 24/670 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1209732662; called by muse, mutect2
- CORIN | c.2271G>A p.W757* | Nonsense Mutation (SNP) | VAF 71/259 reads (27%) | catalogued as rs1441470742; called by muse, mutect2, varscan2
- CPM | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58032644; called by muse, mutect2, varscan2
- CSMD2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 110/493 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs867046579; called by muse, mutect2, varscan2
- CTRB2 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774046523; called by mutect2, varscan2
- CYLC2 | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.725); catalogued as COSV100872494, COSV66338506; called by muse, mutect2, varscan2
- CYP4B1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 68/444 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs745623064, COSV54724715; called by muse, mutect2, varscan2
- CYP4F3 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 84/367 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV55411795; called by muse, mutect2, varscan2
- CYTIP | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 87/482 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.039); catalogued as COSV51633589; called by muse, mutect2, varscan2
- DAPK1 | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 105/481 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as rs758039879; called by muse, mutect2, varscan2
- DCTN1 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 85/429 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs563630664; called by muse, mutect2, varscan2
- DGCR2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 110/562 reads (20%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs764009486; called by muse, mutect2, varscan2
- DNAAF1 | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 44/586 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57577350; called by muse, mutect2
- DNAH11 | c.2140G>A p.G714S | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.779); catalogued as rs1393527464, COSV100179238; called by muse, mutect2
- DNAH17 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 86/433 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs376958134; called by muse, mutect2, varscan2
- DNAH7 | c.7752G>A p.M2584I | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as rs866779881, COSV56766066; called by muse, mutect2, varscan2
- DNMBP | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 98/371 reads (26%) | catalogued as rs755674215, COSV60625548; called by muse, mutect2, varscan2
- EFCAB6 | c.3917C>T p.P1306L | Missense Mutation (SNP) | VAF 98/389 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1292409726, COSV53070442; called by muse, mutect2, varscan2
- EGFR | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 89/455 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV51822575; called by muse, mutect2, varscan2
- EHD3 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 108/545 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762389313; called by muse, mutect2, varscan2
- ELF3 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1445321449, COSV55241261; called by muse, mutect2, varscan2
- EMILIN3 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 156/603 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs773979845; called by muse, mutect2, varscan2
- ENAH | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 90/431 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.982); catalogued as COSV52872545; called by muse, mutect2, varscan2
- ENKUR | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV58632454; called by muse, mutect2, varscan2
- ENPEP | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.742); catalogued as COSV54452809; called by muse, mutect2, varscan2
- ENPEP | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); catalogued as COSV54455416; called by muse, mutect2
- EPHA7 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV65180599; called by muse, mutect2, varscan2
- ESRP1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64409346, COSV64412577; called by muse, mutect2, varscan2
- EVI5L | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 88/419 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1174460263, COSV54483731; called by muse, mutect2, varscan2
- EVX1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 112/560 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.404); catalogued as rs145580913, COSV99763894; called by muse, mutect2, varscan2
- FAP | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 93/499 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1337923591; called by muse, mutect2, varscan2
- FAT4 | c.8044G>A p.E2682K | Missense Mutation (SNP) | VAF 85/348 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58707903; called by muse, mutect2, varscan2
- FGL1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 20/345 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768389622, COSV101112508; called by muse, mutect2
- FKBP5 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 31/498 reads (6%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.71); catalogued as rs767560322, COSV104421629; called by muse, mutect2
- FPR3 | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 118/535 reads (22%) | catalogued as COSV59331921; called by muse, mutect2, varscan2
- FREM1 | c.3541G>A p.D1181N | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as rs771144061, COSV66522565, COSV66530021; called by muse, mutect2, varscan2
- FSTL5 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 103/465 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV60213164; called by muse, mutect2, varscan2
- FYB2 | c.1493G>A p.R498K | Missense Mutation (SNP) | VAF 88/369 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.121); catalogued as rs1296357758; called by muse, mutect2, varscan2
- GABRA3 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64798635; called by muse, mutect2, varscan2
- GABRA6 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV50883486; called by muse, mutect2, varscan2
- GABRG2 | c.797C>T p.S266F (on ENST00000361925 / NM_001375343.1; = p.S226F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/501 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62720442, COSV62721483; called by muse, mutect2
- GMIP | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 153/624 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs1268012285, COSV99179058; called by muse, mutect2, varscan2
- GPT2 | c.579G>A p.T193= | Splice Region (SNP) | VAF 35/277 reads (13%) | catalogued as rs1386493503, COSV60840659; called by muse, mutect2, varscan2
- GRID2 | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as COSV56199230; called by muse, mutect2, varscan2
- HCN4 | c.2846G>A p.R949Q | Missense Mutation (SNP) | VAF 314/698 reads (45%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.007); catalogued as rs752139441; called by muse, mutect2, varscan2
- HOXB1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 146/608 reads (24%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.883); catalogued as rs376245728; called by muse, mutect2, varscan2
- HYDIN | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV101143176; called by muse, mutect2, varscan2
- ICA1 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 110/522 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1469947725; called by muse, mutect2, varscan2
- IGF2BP3 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1238608549; called by muse, mutect2, varscan2
- IGHE | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 80/481 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); catalogued as rs557572691; called by muse, mutect2, varscan2
- IGLV3-25 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 95/515 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs771002794; called by muse, mutect2, varscan2
- IGSF21 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 95/359 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs200292815, COSV52129504, COSV52141695; called by muse, mutect2, varscan2
- IGSF9 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 16/440 reads (4%) | catalogued as rs1031642878; called by muse, mutect2
- IL1RAPL2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 141/327 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61150217; called by muse, mutect2, varscan2
- INPP1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 84/397 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59417294; called by muse, mutect2, varscan2
- ITGA1 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs1258296706; called by muse, mutect2, varscan2
- ITGA8 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65227974; called by muse, mutect2, varscan2
- JPH4 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 41/680 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62509150; called by muse, mutect2
- KANK4 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 90/435 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1213102522, COSV58092037; called by muse, mutect2, varscan2
- KCND2 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.862); catalogued as rs761446789, COSV58602956; called by muse, mutect2, varscan2
- KCND3 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 97/432 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV56185403; called by muse, mutect2, varscan2
- KDM4B | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766480502, COSV50224872; called by muse, mutect2, varscan2
- KHK | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 82/414 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs973664792; called by muse, mutect2, varscan2
- KIF14 | c.3775G>A p.E1259K | Missense Mutation (SNP) | VAF 83/330 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.468); catalogued as COSV66261599; called by muse, mutect2, varscan2
- KIF19 | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 171/734 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs1225162909; called by muse, mutect2, varscan2
- KRT18 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as rs375823747, COSV66316528; called by muse, mutect2, varscan2
- KSR2 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 153/628 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56666743; called by muse, mutect2, varscan2
- LHCGR | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54291907; called by muse, mutect2, varscan2
- LILRA1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 80/476 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as COSV52180971; called by muse, varscan2
- LILRA1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 122/736 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs865785859, COSV52177881, COSV52182882; called by muse, mutect2, varscan2
- LIX1 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 60/305 reads (20%) | catalogued as COSV99172735; called by muse, mutect2, varscan2
- LLGL2 | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 102/454 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51342112; called by muse, mutect2, varscan2
- LMTK3 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); catalogued as rs746709783; called by mutect2, varscan2
- LOXL2 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 19/461 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV66690842; called by muse, mutect2
- LRRC74A | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 99/392 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs1449298385; called by muse, mutect2, varscan2
- LRRIQ3 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100598677; called by muse, mutect2, varscan2
- LRRIQ3 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as rs1176496452, COSV100598983, COSV63047582; called by muse, mutect2, varscan2
- LRRTM3 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 95/441 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.557); catalogued as COSV63670713; called by muse, mutect2, varscan2
- LSR | c.1397G>A p.R466Q (on ENST00000361790; = p.R447Q on NM_015925.6) | Missense Mutation (SNP) | VAF 143/591 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1174837828; called by muse, mutect2, varscan2
- MAP3K5 | c.3880C>T p.P1294S | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs267600831, COSV62889083; called by muse, mutect2, varscan2
- MARF1 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 97/558 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); catalogued as rs557220118; called by muse, mutect2, varscan2
- MEX3C | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV68530272; called by muse, mutect2
- MGAM2 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101522984; called by muse, mutect2, varscan2
- MGAT5B | c.2204C>T p.T735I (on ENST00000569840 / NM_001199172.2; = p.T733I on NM_144677.3) | Missense Mutation (SNP) | VAF 60/369 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV56928211; called by muse, mutect2, varscan2
- MIA | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 68/299 reads (23%) | catalogued as COSV99648110; called by muse, mutect2, varscan2
- MICAL2 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 30/592 reads (5%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.519); catalogued as COSV56318964; called by muse, mutect2
- MKS1 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 74/434 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs886044314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP19 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 57/479 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs762888609, COSV59450393; called by muse, mutect2, varscan2
- MNDA | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs914856154; called by muse, mutect2, varscan2
- MROH5 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 78/356 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs948122500; called by muse, mutect2, varscan2
- MRTFA | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 86/371 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs772930139, COSV62931401, COSV62932866; called by muse, mutect2, varscan2
- MSH2 | c.1883G>A p.G628E | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.913); catalogued as rs879254044; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC5AC | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 109/578 reads (19%) | SIFT deleterious (0); catalogued as rs750263003, COSV62254122; called by muse, mutect2, varscan2
- MYH2 | c.5023G>A p.E1675K | Missense Mutation (SNP) | VAF 28/744 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55437861; called by muse, mutect2
- MYH7B | c.5003G>A p.G1668D | Missense Mutation (SNP) | VAF 139/648 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs202185799; called by muse, mutect2, varscan2
- MYLK | c.5071G>A p.D1691N | Missense Mutation (SNP) | VAF 34/551 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.532); catalogued as COSV60605970; called by muse, mutect2
- MYO1D | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs771404072, COSV59007140; called by muse, mutect2, varscan2
- N4BP2 | c.3647C>T p.S1216L | Missense Mutation (SNP) | VAF 77/372 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs150403405; called by muse, varscan2
- NARS2 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs555887966; called by muse, mutect2, varscan2
- NAV1 | c.3523C>T p.R1175W | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763129333; called by muse, mutect2, varscan2
- NAV1 | c.5074C>T p.R1692C | Missense Mutation (SNP) | VAF 13/445 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55214249; called by muse, mutect2
- NCOR1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1299926374; called by muse, mutect2
- NEB | c.16141G>C p.D5381H | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.877); catalogued as rs1266830125; called by muse, mutect2, varscan2
- NLRP11 | c.2065C>T p.R689W | Missense Mutation (SNP) | VAF 107/458 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV64087074; called by muse, mutect2, varscan2
- NLRP3 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 97/464 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100276285; called by muse, mutect2, varscan2
- NLRP5 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs753935707; called by muse, varscan2
- NLRP8 | c.3131C>T p.S1044F | Missense Mutation (SNP) | VAF 62/317 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as COSV52591799; called by muse, mutect2, varscan2
- NOD2 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1210065116; called by muse, mutect2, varscan2
- NOD2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs1266310979; called by muse, mutect2, varscan2
- NOL4 | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 112/461 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.599); catalogued as COSV52345008; called by muse, mutect2, varscan2
- NOS1AP | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745608624, COSV100723451; called by muse, mutect2, varscan2
- NPM2 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 117/444 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288131842; called by muse, mutect2, varscan2
- NRBF2 | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196836142; called by muse, mutect2, varscan2
- OBP2A | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 97/459 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.037); catalogued as rs1161842925; called by muse, mutect2, varscan2
- OR1E2 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 123/543 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1379890733; called by muse, mutect2, varscan2
- OR1N2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 94/418 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV65460257; called by muse, mutect2, varscan2
- OR2G6 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 102/457 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100598262, COSV58575394; called by muse, mutect2, varscan2
- OR4C16 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 95/440 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs776032076, COSV58942804, COSV58943865; called by muse, mutect2
- OR4D6 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100271922, COSV55659140; called by muse, mutect2, varscan2
- OR51L1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 90/469 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58626067; called by muse, mutect2, varscan2
- OR5D18 | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 97/504 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61737788, COSV61738604; called by muse, mutect2
- OR5K1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100221052, COSV60304383; called by muse, mutect2, varscan2
- OR5W2 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 105/397 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100747746; called by muse, mutect2, varscan2
- OR6F1 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 78/377 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.741); catalogued as COSV57469661; called by muse, mutect2, varscan2
- OSMR | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.644); catalogued as rs769344392, COSV57085792; called by muse, mutect2, varscan2
- PAPPA2 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62772320, COSV62774731; called by muse, mutect2, varscan2
- PAPPA2 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100868379, COSV62798918; called by muse, mutect2, varscan2
- PARD6G | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 183/751 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.084); catalogued as COSV100783440; called by muse, mutect2, varscan2
- PCDHA2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 102/376 reads (27%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.053); catalogued as rs1562152745, COSV65365566; called by muse, mutect2, varscan2
- PCDHB12 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 50/546 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV53396899, COSV53397773; called by muse, mutect2
- PCDHB2 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 46/616 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.564); catalogued as rs560781528, COSV50575108, COSV50582171; called by muse, mutect2
- PCDHGA8 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV53928289; called by muse, mutect2
- PGGHG | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 146/534 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.344); catalogued as rs1202622606; called by muse, mutect2, varscan2
- PHRF1 | c.3616C>T p.L1206F (on ENST00000264555 / NM_001286581.2; = p.L1205F on NM_020901.4) | Missense Mutation (SNP) | VAF 169/831 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs761909912; called by muse, mutect2, varscan2
- PI4KA | c.5728C>T p.R1910C | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs991475637; called by muse, mutect2
- PITPNM3 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 125/646 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs143807935; called by muse, mutect2, varscan2
- PKHD1L1 | c.5914C>T p.H1972Y | Missense Mutation (SNP) | VAF 99/418 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV65739656; called by muse, varscan2
- PLCH1 | c.2066G>A p.R689Q (on ENST00000340059 / NM_001130960.2; = p.R701Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/364 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs894808426, COSV58193990; called by muse, mutect2, varscan2
- PLD1 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1333882356; called by muse, mutect2
- PMEPA1 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 155/614 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55694794; called by muse, mutect2, varscan2
- PP2D1 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 47/200 reads (24%) | catalogued as COSV60749462; called by muse, mutect2, varscan2
- PPEF2 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 113/448 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV54421432; called by muse, mutect2, varscan2
- PPFIA1 | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs774749536, COSV54131411; called by muse, mutect2, varscan2
- PPFIA2 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV61032666, COSV61049301; called by muse, mutect2, varscan2
- PRAMEF5 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs1458568333; called by mutect2, varscan2
- PRDM9 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 71/423 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as rs373825952, COSV99691570; called by muse, mutect2, varscan2
- PRR23B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 154/700 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1463442551, COSV61494743; called by muse, mutect2, varscan2
- PRRG2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 124/596 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55871832; called by muse, mutect2, varscan2
- PTPRB | c.5194C>T p.R1732* | Nonsense Mutation (SNP) | VAF 67/250 reads (27%) | catalogued as rs724159879, COSV54246215; called by muse, mutect2, varscan2
- PWWP3B | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 141/290 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100531652; called by muse, mutect2, varscan2
- PWWP3B | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61800547; called by muse, mutect2, varscan2
- PYGL | c.2177G>A p.G726E | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV99368289; called by muse, mutect2, varscan2
- RAG1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 112/444 reads (25%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.057); catalogued as COSV55025185; called by muse, mutect2, varscan2
- RBBP6 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 93/444 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV60502948; called by muse, mutect2, varscan2
- RBM27 | c.2920C>T p.R974C | Missense Mutation (SNP) | VAF 118/491 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1391679172; called by muse, mutect2, varscan2
- RBM47 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 82/367 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1425927902; called by muse, mutect2, varscan2
- REC8 | c.951G>C p.E317D | Missense Mutation (SNP) | VAF 90/433 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs778046197, COSV61015606, COSV61017571; called by muse, mutect2, varscan2
- REL | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 74/302 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104400087, COSV54361992; called by mutect2, varscan2
- RP1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 131/557 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55125618; called by muse, mutect2, varscan2
- RP1L1 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 128/566 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs201625937; called by muse, mutect2, varscan2
- RUSF1 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as rs1275380960; called by muse, mutect2
- RYR1 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 123/575 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.615); catalogued as rs372652716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.7210G>A p.E2404K | Missense Mutation (SNP) | VAF 97/424 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.27); catalogued as rs111364296, CM091767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAE1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 11/353 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99537693; called by muse, mutect2
- SCGB2A1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.165); catalogued as rs1456037607; called by muse, mutect2, varscan2
- SCN1A | c.5735G>A p.R1912Q (on ENST00000303395 / NM_001202435.3; = p.R1901Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/406 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs373896263; ClinVar: uncertain significance; called by muse, varscan2
- SCN9A | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs779928230, COSV57603107; called by muse, mutect2, varscan2
- SCNN1G | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 136/624 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as rs772835346, COSV55599879; called by muse, mutect2, varscan2
- SEMA5A | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 88/491 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV66803177, COSV66805228; called by muse, mutect2, varscan2
- SEZ6L | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 134/691 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV50666666; called by muse, mutect2, varscan2
- SFRP4 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 93/414 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV71412370; called by muse, mutect2, varscan2
- SIX5 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 125/659 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1306725067; called by muse, mutect2, varscan2
- SIX5 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 127/663 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs962401818; called by muse, mutect2, varscan2
- SLC12A2 | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 74/367 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99321641; called by muse, mutect2, varscan2
- SLC12A3 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 91/453 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs1233683747, CX021482; called by muse, mutect2, varscan2
- SLC4A1 | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 92/420 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV52259970; called by muse, mutect2, varscan2
- SLC5A5 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 87/394 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1246187175; called by muse, mutect2, varscan2
- SLC8A2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 105/542 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as COSV52640811; called by muse, mutect2, varscan2
- SLC9C1 | c.3194A>C p.K1065T | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV59890674; called by muse, mutect2, varscan2
- SLCO1B1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV57006565; called by muse, mutect2, varscan2
- SORCS3 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.893); catalogued as COSV63806483; called by muse, mutect2, varscan2
- SPART | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 95/458 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62087312; called by muse, mutect2, varscan2
- SPATA31E1 | c.3751C>T p.Q1251* | Nonsense Mutation (SNP) | VAF 121/575 reads (21%) | catalogued as COSV57790730; called by muse, mutect2, varscan2
- SPEG | c.4072C>T p.R1358W | Missense Mutation (SNP) | VAF 120/531 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775313654, COSV104395116; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 93/399 reads (23%) | PolyPhen probably damaging (0.995); catalogued as COSV100082265; called by muse, mutect2, varscan2
- STAB2 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 67/339 reads (20%) | catalogued as COSV66340538; called by muse, mutect2, varscan2
- STAP1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as COSV55328760; called by muse, mutect2, varscan2
- STYXL2 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 135/586 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV54805288; called by muse, mutect2, varscan2
- SUGP1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 124/531 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99895514; called by muse, mutect2, varscan2
- SUN5 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV50071348; called by muse, mutect2
- SYDE2 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 133/519 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs768555839; called by muse, mutect2, varscan2
- SYT2 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 107/500 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs911413010, COSV66143424; called by muse, mutect2, varscan2
- TAF1L | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as COSV54258077; called by muse, mutect2, varscan2
- TENM2 | c.3745G>A p.G1249R (on ENST00000518659 / NM_001122679.2; = p.G1017R on NM_001080428.3) | Missense Mutation (SNP) | VAF 84/484 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009161864; called by muse, mutect2, varscan2
- TENT5D | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382511; called by muse, mutect2
- THSD1 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 117/514 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs144799411; called by muse, mutect2, varscan2
- TIA1 | c.763C>T p.R255W (on ENST00000433529 / NM_001351511.1; = p.R244W on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224666937, COSV57006419; called by muse, mutect2, varscan2
- TLR10 | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 109/467 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775330378, COSV58299408; called by muse, mutect2, varscan2
- TM2D3 | c.518C>T p.P173L (on ENST00000333202 / NM_078474.3; = p.P147L on NM_025141.3) | Missense Mutation (SNP) | VAF 142/318 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100309684; called by muse, mutect2, varscan2
- TMEM200A | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 97/430 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV51660509; called by muse, mutect2, varscan2
- TMEM200A | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 102/402 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772523704, COSV51659526; called by muse, mutect2, varscan2
- TMEM79 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 30/764 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.082); catalogued as COSV99827859, COSV99828034; called by muse, mutect2
- TMPRSS15 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 15/323 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53053230; called by muse, mutect2
- TMPRSS2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 127/531 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs770444484, COSV59827325; called by muse, mutect2, varscan2
- TNR | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 127/519 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54878289; called by muse, mutect2, varscan2
- TRPM5 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 102/526 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50151083; called by muse, mutect2, varscan2
- TTN | c.88040G>A p.R29347K (on ENST00000591111; = p.R21923K on NM_003319.4) | Missense Mutation (SNP) | VAF 75/346 reads (22%) | PolyPhen probably damaging (0.987); catalogued as COSV60196658; called by muse, mutect2, varscan2
- TTN | c.56291G>A p.G18764E (on ENST00000591111; = p.G11340E on NM_003319.4) | Missense Mutation (SNP) | VAF 82/394 reads (21%) | PolyPhen probably damaging (1); catalogued as rs749894610; called by muse, mutect2, varscan2
- TTN | c.52913G>A p.R17638K (on ENST00000591111; = p.R10214K on NM_003319.4) | Missense Mutation (SNP) | VAF 56/233 reads (24%) | PolyPhen benign (0.005); catalogued as rs1288705204; called by muse, mutect2, varscan2
- TTN | c.48901G>A p.E16301K (on ENST00000591111; = p.E8877K on NM_003319.4) | Missense Mutation (SNP) | VAF 74/325 reads (23%) | PolyPhen benign (0.033); catalogued as COSV60169071; called by muse, mutect2, varscan2
- TTN | c.25018G>A p.G8340R (on ENST00000591111; = p.G7413R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/454 reads (23%) | PolyPhen possibly damaging (0.819); catalogued as COSV100632012, COSV60004498; called by muse, varscan2
- TTN | c.6208G>A p.E2070K (on ENST00000591111; = p.E2024K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/582 reads (3%) | PolyPhen benign (0.173); catalogued as COSV100636213; called by muse, mutect2
- TTN | c.2762G>A p.G921E (on ENST00000591111; = p.G875E on NM_003319.4) | Missense Mutation (SNP) | VAF 67/343 reads (20%) | PolyPhen benign (0); catalogued as COSV59905102; called by muse, mutect2, varscan2
- TYRO3 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 42/621 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.296); catalogued as rs1285101524; called by muse, mutect2
- UGP2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as rs776077450, COSV61427388; called by muse, mutect2, varscan2
- UGT3A1 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV57102201; called by muse, mutect2, varscan2
- USH1G | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 138/550 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV58883878; called by muse, mutect2, varscan2
- USP17L2 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 176/1361 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs770234887, COSV61555695; called by muse, mutect2, varscan2
- USP6NL | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 56/546 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs77522325; called by muse, mutect2
- VSTM2A | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 133/558 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs200451254, COSV56492709; called by muse, mutect2, varscan2
- WDR26 | c.1745C>T p.S582F (on ENST00000414423 / NM_001379403.1; = p.S482F on NM_025160.7) | Missense Mutation (SNP) | VAF 97/348 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV99691466; called by muse, mutect2, varscan2
- WDR35 | c.3487C>T p.L1163F (on ENST00000345530 / NM_001006657.2; = p.L1152F on NM_020779.4) | Missense Mutation (SNP) | VAF 77/458 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs759903398; called by muse, mutect2, varscan2
- XAGE5 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV63568015; called by muse, mutect2, varscan2
- ZFP92 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 142/306 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1395124332; called by muse, mutect2, varscan2
- ZMIZ2 | c.996C>T p.P332= | Splice Region (SNP) | VAF 98/441 reads (22%) | catalogued as rs751534313, COSV99537052; called by muse, mutect2, varscan2
- ZNF536 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 147/671 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs747462173, COSV100835934, COSV62817581; called by muse, mutect2, varscan2
- ZNF711 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 107/203 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99341351; called by muse, mutect2, varscan2
- ZNF804A | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV56449169; called by muse, mutect2, varscan2
- ZNF860 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 60/301 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1409795583; called by muse, mutect2, varscan2
- ZSCAN5B | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 73/308 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs781291132; called by muse, mutect2, varscan2
- ABCA3 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 125/580 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCD2 | c.1969T>G p.S657A | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- ABCD2 | c.1967T>A p.I656N | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- AC025287.4 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 75/353 reads (21%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ACAN | c.6775G>A p.D2259N | Missense Mutation (SNP) | VAF 16/534 reads (3%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.912); called by muse, mutect2
- ADAM7 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTSL2 | c.371T>A p.V124E | Missense Mutation (SNP) | VAF 100/494 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ADGRE1 | c.1580G>A p.G527D | Missense Mutation (SNP) | VAF 81/340 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADGRG4 | c.6722C>T p.S2241F | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ADGRV1 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ADGRV1 | c.9803C>G p.S3268C | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADH1B | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- AJM1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 118/604 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ALMS1 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 90/530 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ALOX15B | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 114/539 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ALPK2 | c.2197T>A p.F733I | Missense Mutation (SNP) | VAF 107/488 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- AMELX | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ANKRD36B | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD7 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AP3D1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 102/421 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARFGEF1 | c.1986del p.Y662* | Frame Shift Del (DEL) | VAF 108/423 reads (26%) | called by mutect2, pindel, varscan2
- ARHGEF15 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 145/575 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF5 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by mutect2, varscan2
- ARID3C | c.393G>A p.G131= | Splice Region (SNP) | VAF 70/284 reads (25%) | called by muse, mutect2, varscan2
- ARRDC1 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 166/662 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ASAP2 | c.1892C>T p.T631I | Missense Mutation (SNP) | VAF 81/421 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAHCC1 | c.6659C>T p.A2220V | Missense Mutation (SNP) | VAF 109/618 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BBS10 | c.13A>T p.M5L | Missense Mutation (SNP) | VAF 100/399 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BCLAF1 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- BRIP1 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 104/475 reads (22%) | called by muse, mutect2, varscan2
- C19orf85 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 107/543 reads (20%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2, varscan2
- C1orf127 | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C4orf54 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 112/526 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- C6 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASQ2 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC18 | c.2016G>A p.M672I (on ENST00000343253 / NM_001306076.1; = p.M673I on NM_206886.4) | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC97 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, varscan2
- CCDC97 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- CD1C | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CDH12 | c.1697T>A p.F566Y | Missense Mutation (SNP) | VAF 122/463 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- CDH6 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CDHR5 | c.1541G>C p.G514A (on ENST00000358353 / NM_001171968.2; = p.G520A on NM_021924.5) | Missense Mutation (SNP) | VAF 154/843 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.037); called by muse, mutect2
- CLDN8 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 131/516 reads (25%) | called by muse, mutect2, varscan2
- CNOT4 | c.971C>A p.S324Y (on ENST00000315544 / NM_001190848.1; = p.S321Y on NM_013316.4) | Missense Mutation (SNP) | VAF 105/335 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- COL11A1 | c.2610G>A p.R870= | Splice Region (SNP) | VAF 66/324 reads (20%) | called by muse, mutect2, varscan2
- COL28A1 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 67/357 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL6A5 | c.4496G>A p.R1499K | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- CPED1 | c.2366G>C p.R789T | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRAMP1 | c.3569C>T p.S1190F | Missense Mutation (SNP) | VAF 109/540 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CREBBP | c.1543C>T p.H515Y | Missense Mutation (SNP) | VAF 100/435 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- CRYBG2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 126/625 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CSMD2 | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 128/512 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CSMD3 | c.9175C>T p.P3059S (on ENST00000297405 / NM_001363185.1; = p.P2890S on NM_052900.3) | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CYP2A13 | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 97/409 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- DAGLB | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 96/428 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DAO | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCAF11 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 99/512 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX3X | c.1706G>A p.W569* (on ENST00000399959; = p.W570* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 28/231 reads (12%) | called by muse, mutect2, varscan2
- DDX5 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DIXDC1 | c.938C>T p.S313F (on ENST00000440460 / NM_001037954.4; = p.S102F on NM_033425.4) | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DLGAP3 | c.2592C>A p.F864L | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DNAH17 | c.2862G>A p.M954I | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- DNAH5 | c.10520G>A p.S3507N | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, varscan2
- DNAH5 | c.10465G>A p.A3489T | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- DNAH6 | c.6212C>T p.P2071L | Missense Mutation (SNP) | VAF 82/387 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH6 | c.8251G>A p.D2751N | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DONSON | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOP1B | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 95/465 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPP10 | c.1353G>T p.Q451H | Missense Mutation (SNP) | VAF 87/381 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DSCAM | c.5158G>A p.D1720N | Missense Mutation (SNP) | VAF 99/478 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- DSG2 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 86/413 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- DSG3 | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EFCAB8 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EHD3 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 107/548 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ELMO2 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EML6 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); called by muse, varscan2
- ENPP4 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- F2R | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM160A1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 130/541 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM193B | c.2372G>A p.R791K | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- FLG2 | c.4036A>G p.S1346G | Missense Mutation (SNP) | VAF 120/547 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FOXO1 | c.1568C>T p.T523I | Missense Mutation (SNP) | VAF 100/502 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FOXS1 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 118/604 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- GALNT16 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 109/466 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- GIMAP2 | c.586A>T p.K196* | Nonsense Mutation (SNP) | VAF 99/402 reads (25%) | called by muse, mutect2, varscan2
- GOLGA3 | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 115/512 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- GON4L | c.3815C>T p.P1272L | Missense Mutation (SNP) | VAF 17/490 reads (3%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2
- GPR139 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 111/511 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- GRIA1 | c.2713G>A p.G905R | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- GRIP2 | c.3023G>A p.G1008D (on ENST00000619221; = p.G911D on NM_001080423.4) | Missense Mutation (SNP) | VAF 119/487 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- GRIP2 | c.1657G>A p.E553K (on ENST00000619221; = p.E456K on NM_001080423.4) | Missense Mutation (SNP) | VAF 122/515 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GSDMA | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 81/384 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GYS1 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 108/507 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HHEX | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 115/516 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- HHLA2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 113/540 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- HK1 | c.2198C>T p.S733F | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HOXB8 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 138/606 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, varscan2
- HTR2A | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 23/661 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HTRA1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGFN1 | c.1807G>A p.D603N (on ENST00000295591 / NM_001367841.1; = p.D3060N on NM_001164586.2) | Missense Mutation (SNP) | VAF 131/638 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- IL36A | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 112/543 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL3RA | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1057G>A p.G353R (on ENST00000485419 / NM_001197113.1; = p.G277R on NM_014575.3) | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA11 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 48/600 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- ITGAL | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 67/321 reads (21%) | called by muse, mutect2, varscan2
- ITGB6 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 77/354 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH1 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 120/554 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KCNH7 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 53/220 reads (24%) | called by muse, mutect2, varscan2
- KCNJ9 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 141/607 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, varscan2
- KIAA0100 | c.6218C>A p.P2073H | Missense Mutation (SNP) | VAF 90/404 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- KIAA1671 | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 109/452 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- KIF1A | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR2DL3 | c.1010C>A p.P337Q | Missense Mutation (SNP) | VAF 109/498 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLRC2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 54/477 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LAMC2 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- LETM1 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIPJ | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- LIPK | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- LMAN2 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 104/524 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- LRFN3 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 118/529 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LRIT3 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- LRRN4 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 133/629 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAGEC3 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 45/367 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MALRD1 | c.5654C>T p.S1885F | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- MAN1A1 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K5 | c.1634T>A p.F545Y | Missense Mutation (SNP) | VAF 84/331 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAP3K5 | c.1633T>A p.F545I | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP4K3 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MASP2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAU2 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 100/446 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- MDGA1 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 156/556 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2
- MDH1B | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGA | c.6732G>A p.W2244* (on ENST00000219905 / NM_001164273.1; = p.W2035* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 89/312 reads (29%) | called by muse, mutect2, varscan2
- MRAS | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 111/458 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 121/509 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MROH7 | c.2549C>T p.S850F | Missense Mutation (SNP) | VAF 95/419 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A12 | c.416_422del p.F139Sfs*18 | Frame Shift Del (DEL) | VAF 72/320 reads (23%) | called by mutect2, pindel, varscan2
- MUC16 | c.28319C>T p.S9440F | Missense Mutation (SNP) | VAF 98/485 reads (20%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- MUC17 | c.877A>G p.S293G | Missense Mutation (SNP) | VAF 119/409 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.6917C>T p.S2306F | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- MUC22 | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 148/798 reads (19%) | SIFT tolerated (0.69); called by muse, mutect2, varscan2
- MUC5B | c.3583G>A p.G1195S | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MXRA5 | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 110/248 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH1 | c.3501G>A p.M1167I | Missense Mutation (SNP) | VAF 114/607 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO5B | c.3980G>A p.G1327E | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- MYOZ1 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 146/621 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- MYPN | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHSL1 | c.946T>A p.F316I | Missense Mutation (SNP) | VAF 109/498 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NIBAN1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 76/301 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- NISCH | c.2613del p.A872Pfs*101 | Frame Shift Del (DEL) | VAF 128/582 reads (22%) | called by mutect2, pindel, varscan2
- NPIPB6 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 120/748 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- NPY4R | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 96/1180 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2
- NUTM2B | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 168/1441 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OGDH | c.1683G>C p.K561N | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- OR14I1 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 70/375 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51I1 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 20/480 reads (4%) | called by muse, mutect2
- OR52M1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 73/421 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5G3 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 88/407 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- OR5L2 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 87/402 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR5T1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 53/703 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- OR7A17 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 89/370 reads (24%) | called by muse, mutect2, varscan2
- OSBP | c.1254T>A p.N418K | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OTOGL | c.2736G>A p.W912* (on ENST00000547103; = p.W903* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 57/168 reads (34%) | called by muse, mutect2, varscan2
- OTOP2 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 79/399 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PARP3 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 93/433 reads (21%) | called by muse, mutect2, varscan2
- PCDH11X | c.3104C>T p.P1035L | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.076); called by muse, mutect2
- PCDHB2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 113/470 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.8974C>T p.P2992S | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PFKFB4 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 74/384 reads (19%) | PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PGF | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.04); called by muse, mutect2
- PI4K2A | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 113/529 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PIK3C2A | c.3255T>G p.F1085L | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLA2G15 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- PLCE1 | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PLXNB1 | c.4286C>G p.T1429R | Missense Mutation (SNP) | VAF 147/618 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PNPLA2 | c.274A>C p.K92Q | Missense Mutation (SNP) | VAF 140/537 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- POM121L12 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 26/800 reads (3%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.637); called by muse, mutect2
- POTEG | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 60/525 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.892C>A p.H298N | Missense Mutation (SNP) | VAF 91/413 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PPP1R36 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 46/626 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- PRAMEF5 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.287); called by mutect2, varscan2
- PRDM12 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 79/332 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRSS51 | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 132/477 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PSD | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 137/621 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PSMF1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 124/562 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRK | c.3041T>A p.V1014E (on ENST00000368215 / NM_001291984.2; = p.V1015E on NM_002844.4) | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- PYGL | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 80/358 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- RANBP17 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RASA3 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 75/354 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RBM42 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 128/523 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- RCSD1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 51/676 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2
- RET | c.2134C>T p.L712= | Splice Region (SNP) | VAF 32/350 reads (9%) | called by muse, mutect2
- RNF141 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 106/417 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RPN2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 111/485 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPRD2 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 82/417 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPRD2 | c.3775C>T p.P1259S | Missense Mutation (SNP) | VAF 146/644 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RTL9 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 132/297 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- RUBCN | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCLT1 | c.2048T>A p.M683K | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.346); called by muse, mutect2
- SCUBE1 | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 143/628 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SDR42E2 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 94/475 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SEC14L2 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 94/498 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SELL | c.383G>A p.G128E (on ENST00000650983; = p.G115E on NM_000655.5) | Missense Mutation (SNP) | VAF 117/481 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB5 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETD1B | c.5873C>T p.S1958F | Missense Mutation (SNP) | VAF 81/356 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SHANK2 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 96/503 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHPRH | c.4340C>T p.T1447I (on ENST00000275233 / NM_001042683.3; = p.T1451I on NM_173082.3) | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIRT5 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 142/554 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A24 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 110/449 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC25A12 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC28A1 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 149/297 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC35B3 | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOCS7 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 95/504 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPHKAP | c.2064G>A p.M688I | Missense Mutation (SNP) | VAF 109/512 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SREBF1 | c.1786G>A p.G596R | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRRM1 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 110/491 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- STAC2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- STH | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 162/713 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- STX1A | c.503T>A p.M168K | Missense Mutation (SNP) | VAF 116/608 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SYNE2 | c.13546C>T p.Q4516* | Nonsense Mutation (SNP) | VAF 56/296 reads (19%) | called by muse, mutect2, varscan2
- SYT1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 29/614 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.74); called by muse, mutect2
- TADA3 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TAT | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 78/381 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRKH | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 114/438 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, varscan2
- TEX11 | c.773C>T p.S258F (on ENST00000344304; = p.S243F on NM_031276.3) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- THEGL | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 71/351 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- TLR10 | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 91/354 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TMCO1 | c.65_67del p.G22del | In Frame Del (DEL) | VAF 94/405 reads (23%) | called by mutect2, pindel, varscan2
- TNNT3 | c.646G>A p.E216K (on ENST00000397301 / NM_001367846.1; = p.E205K on NM_006757.4) | Missense Mutation (SNP) | VAF 98/453 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TNRC6A | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 113/543 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- TNXB | c.6824C>T p.P2275L (on ENST00000647633; = p.P2028L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/600 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOR2A | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 77/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TPTE | c.619C>T p.H207Y (on ENST00000618007 / NM_199261.4; = p.H189Y on NM_199259.4) | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); called by muse, mutect2
- TRAV34 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 76/408 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRMT6 | c.1383G>A p.M461I | Missense Mutation (SNP) | VAF 114/516 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPC4 | c.1361T>C p.V454A | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- TRPM4 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 87/449 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TRPM7 | c.3935C>T p.P1312L | Missense Mutation (SNP) | VAF 140/293 reads (48%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTN | c.46778C>T p.S15593F (on ENST00000591111; = p.S8169F on NM_003319.4) | Missense Mutation (SNP) | VAF 82/426 reads (19%) | PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TTN | c.36658G>A p.E12220K (on ENST00000591111; = p.E4796K on NM_003319.4) | Missense Mutation (SNP) | VAF 84/362 reads (23%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.34681C>T p.P11561S (on ENST00000591111; = p.P10634S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/503 reads (20%) | PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TTN | c.11892G>A p.M3964I (on ENST00000591111; = p.M3918I on NM_003319.4) | Missense Mutation (SNP) | VAF 91/412 reads (22%) | called by muse, mutect2, varscan2
- UGT1A3 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 105/501 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13C | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP26 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 98/189 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- VEGFC | c.813C>T p.D271= | Splice Region (SNP) | VAF 51/209 reads (24%) | called by muse, mutect2, varscan2
- VSIG10L | c.1868G>A p.G623E | Missense Mutation (SNP) | VAF 25/747 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2
- VWA1 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 115/413 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- VWA5B1 | c.2143A>C p.N715H | Missense Mutation (SNP) | VAF 76/373 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- WDFY4 | c.3020C>T p.S1007F | Missense Mutation (SNP) | VAF 101/442 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- WDHD1 | c.3065T>C p.F1022S | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- WDR48 | c.974C>T p.T325I | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR82 | c.814A>T p.I272L | Missense Mutation (SNP) | VAF 107/450 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- WFIKKN1 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 129/561 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- WHRN | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 130/587 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- XYLT2 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 120/586 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZMYM6 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- ZNF300 | c.1606C>A p.L536I | Missense Mutation (SNP) | VAF 123/525 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF415 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 125/503 reads (25%) | called by muse, mutect2, varscan2
- ZNF415 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 120/505 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF431 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ZNF462 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 124/527 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF605 | c.1831C>T p.H611Y | Missense Mutation (SNP) | VAF 121/459 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ZNF729 | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF76 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 79/447 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF841 | c.751C>T p.H251Y (on ENST00000426391 / NM_001369830.1; = p.H367Y on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/461 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- A2ML1 | c.3871C>T p.L1291= | Silent (SNP) | VAF 104/449 reads (23%) | called by muse, mutect2, varscan2
- ABHD16A | c.390C>T p.I130= | Silent (SNP) | VAF 154/602 reads (26%) | called by muse, mutect2, varscan2
- ABHD4 | c.1011C>T p.I337= | Silent (SNP) | VAF 82/405 reads (20%) | catalogued as rs778474374; called by muse, mutect2, varscan2
- ACAP3 | c.1752C>T p.P584= | Silent (SNP) | VAF 123/553 reads (22%) | catalogued as rs967786877; called by muse, mutect2, varscan2
- ACE | c.2397C>T p.L799= | Silent (SNP) | VAF 111/483 reads (23%) | catalogued as COSV52013354; called by muse, mutect2, varscan2
- ACSM4 | c.294C>T p.S98= | Silent (SNP) | VAF 24/604 reads (4%) | called by muse, mutect2
- ADAD1 | c.1479C>T p.I493= | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as COSV56647243, COSV99635176; called by muse, mutect2, varscan2
- ADAM7 | c.60C>T p.F20= | Silent (SNP) | VAF 70/280 reads (25%) | called by muse, mutect2, varscan2
- ADCY8 | c.3303C>T p.I1101= | Silent (SNP) | VAF 68/346 reads (20%) | catalogued as rs763870480, COSV53913849; called by muse, mutect2, varscan2
- ADGRG4 | c.7035G>A p.L2345= | Silent (SNP) | VAF 111/200 reads (56%) | called by muse, mutect2, varscan2
- AGAP6 | c.1858C>T p.L620= (on ENST00000374056 / NM_001365867.1; = p.L643= on NM_001077665.2) | Silent (SNP) | VAF 116/809 reads (14%) | called by muse, mutect2
- AGBL1 | c.3159C>T p.L1053= | Silent (SNP) | VAF 185/415 reads (45%) | catalogued as rs371637847; called by muse, mutect2, varscan2
- AHDC1 | c.1059C>T p.P353= | Silent (SNP) | VAF 131/638 reads (21%) | called by muse, mutect2, varscan2
- AIFM2 | c.9C>T p.S3= | Silent (SNP) | VAF 63/333 reads (19%) | called by muse, mutect2, varscan2
- AMPD3 | c.1449G>A p.K483= (on ENST00000396553 / NM_001025389.2; = p.K492= on NM_000480.3) | Silent (SNP) | VAF 66/349 reads (19%) | called by muse, mutect2, varscan2
- ANKFN1 | c.3012C>T p.I1004= (on ENST00000653862; = p.I857= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/483 reads (3%) | called by muse, mutect2
- ANKRD7 | c.282C>T p.S94= | Silent (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- ANO8 | c.648T>C p.I216= | Silent (SNP) | VAF 101/418 reads (24%) | called by muse, mutect2, varscan2
- ANPEP | c.1911G>A p.E637= | Silent (SNP) | VAF 104/422 reads (25%) | called by muse, mutect2, varscan2
- APOB | c.11001A>T p.G3667= | Silent (SNP) | VAF 128/523 reads (24%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.2856C>T p.S952= | Silent (SNP) | VAF 24/673 reads (4%) | called by muse, mutect2
- ASAP2 | c.1893C>T p.T631= | Silent (SNP) | VAF 83/422 reads (20%) | catalogued as rs138309057, COSV99856907; called by muse, mutect2, varscan2
- ATG2B | c.3600C>T p.L1200= | Silent (SNP) | VAF 85/341 reads (25%) | catalogued as rs755422836; called by muse, mutect2, varscan2
- AWAT2 | c.66C>T p.S22= | Silent (SNP) | VAF 104/232 reads (45%) | catalogued as rs1187080205; called by muse, mutect2, varscan2
- AXIN1 | c.2178C>T p.S726= | Silent (SNP) | VAF 89/379 reads (23%) | catalogued as rs1161259913; called by muse, mutect2, varscan2
- BAHCC1 | c.6660C>T p.A2220= | Silent (SNP) | VAF 105/612 reads (17%) | catalogued as rs782328667; called by muse, mutect2, varscan2
- BAIAP2 | c.708C>T p.I236= | Silent (SNP) | VAF 133/614 reads (22%) | called by muse, mutect2, varscan2
- BANK1 | c.1980G>A p.R660= | Silent (SNP) | VAF 67/254 reads (26%) | catalogued as rs267599965, COSV100536572; called by muse, mutect2, varscan2
- BCL9L | c.3894C>T p.L1298= | Silent (SNP) | VAF 153/519 reads (29%) | catalogued as rs562643900, COSV52687248; called by muse, mutect2, varscan2
- BEND3 | c.1105C>T p.L369= | Silent (SNP) | VAF 106/463 reads (23%) | called by muse, mutect2, varscan2
- BMPER | c.1233G>A p.R411= | Silent (SNP) | VAF 123/683 reads (18%) | called by muse, mutect2, varscan2
- BRD9 | c.300C>T p.H100= | Silent (SNP) | VAF 19/579 reads (3%) | catalogued as rs1047035749; called by muse, mutect2
- BTNL9 | c.486G>A p.E162= | Silent (SNP) | VAF 86/385 reads (22%) | called by muse, mutect2, varscan2
- C10orf71 | c.2271G>A p.R757= | Silent (SNP) | VAF 90/444 reads (20%) | called by muse, mutect2, varscan2
- C10orf71 | c.3168C>T p.S1056= | Silent (SNP) | VAF 121/644 reads (19%) | called by muse, mutect2, varscan2
- C4orf54 | c.2325C>T p.P775= | Silent (SNP) | VAF 113/525 reads (22%) | catalogued as rs778926663; called by muse, mutect2, varscan2
- C6orf132 | c.3162C>T p.F1054= | Silent (SNP) | VAF 127/621 reads (20%) | called by muse, mutect2, varscan2
- C7orf26 | c.552C>T p.S184= | Silent (SNP) | VAF 29/424 reads (7%) | catalogued as rs747882149, COSV60419369; called by muse, mutect2
- CACNA1A | c.6033C>T p.A2011= | Silent (SNP) | VAF 106/533 reads (20%) | catalogued as rs369675855; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CACNA1G | c.5667C>T p.P1889= | Silent (SNP) | VAF 152/649 reads (23%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.2811C>T p.S937= (on ENST00000479441 / NM_001174051.3; = p.S930= on NM_006030.4) | Silent (SNP) | VAF 107/506 reads (21%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.429G>A p.G143= | Silent (SNP) | VAF 78/410 reads (19%) | catalogued as rs267599904, COSV55518510; called by muse, mutect2, varscan2
- CACNG4 | c.969G>A p.R323= | Silent (SNP) | VAF 17/338 reads (5%) | catalogued as COSV50928019; called by muse, mutect2
- CALY | c.85C>T p.L29= | Silent (SNP) | VAF 122/560 reads (22%) | called by muse, mutect2, varscan2
- CCAR1 | c.2910C>T p.L970= | Silent (SNP) | VAF 74/308 reads (24%) | catalogued as COSV99771471; called by muse, mutect2, varscan2
- CCDC180 | c.4287C>T p.F1429= | Silent (SNP) | VAF 88/379 reads (23%) | called by muse, mutect2, varscan2
- CD163L1 | c.2559G>A p.G853= | Silent (SNP) | VAF 93/380 reads (24%) | catalogued as COSV100550048; called by muse, mutect2, varscan2
- CDH19 | c.342C>T p.I114= | Silent (SNP) | VAF 80/350 reads (23%) | catalogued as COSV100050680; called by muse, mutect2, varscan2
- CELSR1 | c.4449C>T p.G1483= | Silent (SNP) | VAF 84/357 reads (24%) | called by muse, mutect2, varscan2
- CERCAM | c.624C>T p.F208= | Silent (SNP) | VAF 138/587 reads (24%) | called by muse, mutect2, varscan2
- CFAP410 | c.489C>T p.S163= | Silent (SNP) | VAF 42/730 reads (6%) | called by muse, mutect2
- CFAP47 | c.4011T>C p.N1337= | Silent (SNP) | VAF 46/103 reads (45%) | called by muse, varscan2
- CHAMP1 | c.1986C>T p.S662= | Silent (SNP) | VAF 85/394 reads (22%) | called by muse, mutect2, varscan2
- CHID1 | c.853C>T p.L285= | Silent (SNP) | VAF 85/456 reads (19%) | called by muse, mutect2, varscan2
- CHRNB4 | c.132C>T p.I44= | Silent (SNP) | VAF 231/503 reads (46%) | catalogued as rs1245620516; called by muse, mutect2, varscan2
- CLASP1 | c.3973C>T p.L1325= | Silent (SNP) | VAF 70/385 reads (18%) | called by muse, mutect2, varscan2
- CLIP2 | c.1743C>T p.L581= | Silent (SNP) | VAF 138/709 reads (19%) | catalogued as COSV99792272, COSV99792321; called by muse, mutect2, varscan2
- CLIP2 | c.2950C>T p.L984= | Silent (SNP) | VAF 247/668 reads (37%) | called by muse, varscan2
- CLN5 | c.315A>G p.K105= | Silent (SNP) | VAF 54/317 reads (17%) | called by muse, mutect2, varscan2
- CNOT4 | c.972C>T p.S324= (on ENST00000315544 / NM_001190848.1; = p.S321= on NM_013316.4) | Silent (SNP) | VAF 104/335 reads (31%) | called by muse, mutect2, varscan2
- COL4A3 | c.2040G>A p.G680= | Silent (SNP) | VAF 88/355 reads (25%) | called by muse, mutect2, varscan2
- CPEB3 | c.1257C>T p.A419= | Silent (SNP) | VAF 120/532 reads (23%) | called by muse, mutect2, varscan2
- CPXM1 | c.1119G>A p.L373= | Silent (SNP) | VAF 110/524 reads (21%) | called by muse, mutect2, varscan2
- CSHL1 | c.225C>T p.F75= | Silent (SNP) | VAF 91/418 reads (22%) | catalogued as COSV51987709; called by muse, mutect2, varscan2
- CSMD1 | c.882C>T p.F294= | Silent (SNP) | VAF 59/240 reads (25%) | catalogued as rs772061769, COSV101211898; called by muse, mutect2, varscan2
- CST2 | c.318C>T p.F106= | Silent (SNP) | VAF 15/550 reads (3%) | catalogued as COSV59030710; called by muse, mutect2
- CYP1A1 | c.1128C>T p.F376= | Silent (SNP) | VAF 71/347 reads (20%) | called by muse, mutect2, varscan2
- CYSLTR1 | c.673C>T p.L225= | Silent (SNP) | VAF 17/219 reads (8%) | called by muse, mutect2
- CYTIP | c.54C>T p.F18= | Silent (SNP) | VAF 96/410 reads (23%) | catalogued as rs1451812782; called by muse, mutect2, varscan2
- DCAF11 | c.1341C>T p.P447= | Silent (SNP) | VAF 99/509 reads (19%) | called by muse, mutect2, varscan2
- DCDC2 | c.1254G>A p.Q418= | Silent (SNP) | VAF 14/499 reads (3%) | called by muse, mutect2
- DDX60 | c.2499G>A p.T833= | Silent (SNP) | VAF 47/245 reads (19%) | catalogued as rs746559865, COSV67094881; called by muse, mutect2, varscan2
- DIS3 | c.1725G>A p.T575= | Silent (SNP) | VAF 52/226 reads (23%) | catalogued as rs182902184, COSV66707256; called by muse, mutect2, varscan2
- DNAH1 | c.5751C>T p.L1917= | Silent (SNP) | VAF 64/346 reads (18%) | called by muse, mutect2, varscan2
- DNAH10 | c.2394G>T p.L798= (on ENST00000409039; = p.L737= on NM_207437.3) | Silent (SNP) | VAF 56/317 reads (18%) | called by muse, varscan2
- DNAH5 | c.9115C>T p.L3039= | Silent (SNP) | VAF 75/270 reads (28%) | called by muse, mutect2, varscan2
- DNAH5 | c.3079C>T p.L1027= | Silent (SNP) | VAF 38/618 reads (6%) | called by muse, mutect2
- DRC1 | c.555G>A p.K185= | Silent (SNP) | VAF 87/354 reads (25%) | catalogued as rs979755651; called by muse, mutect2, varscan2
- DSP | c.1284C>A p.I428= | Silent (SNP) | VAF 86/295 reads (29%) | catalogued as COSV65794622; called by muse, mutect2, varscan2
- ECE2 | c.237C>T p.S79= | Silent (SNP) | VAF 81/358 reads (23%) | called by muse, mutect2, varscan2
- EDEM2 | c.1524C>T p.L508= | Silent (SNP) | VAF 118/551 reads (21%) | catalogued as COSV63259494; called by muse, mutect2, varscan2
- EIF2S3B | c.849C>T p.I283= | Silent (SNP) | VAF 159/658 reads (24%) | catalogued as rs768269034; called by muse, mutect2, varscan2
- ELF3 | c.12C>T p.T4= | Silent (SNP) | VAF 50/260 reads (19%) | called by muse, mutect2, varscan2
- ELOVL6 | c.609C>T p.I203= | Silent (SNP) | VAF 111/519 reads (21%) | called by muse, mutect2, varscan2
- EPHB3 | c.726C>T p.I242= | Silent (SNP) | VAF 155/619 reads (25%) | called by muse, mutect2, varscan2
- FAM13C | c.1587G>A p.R529= | Silent (SNP) | VAF 58/353 reads (16%) | called by muse, mutect2, varscan2
- FAM234A | c.1485C>T p.I495= | Silent (SNP) | VAF 107/526 reads (20%) | catalogued as COSV51454035; called by muse, mutect2, varscan2
- FAT2 | c.4410C>T p.V1470= | Silent (SNP) | VAF 100/493 reads (20%) | called by muse, mutect2, varscan2
- FBXO39 | c.330C>T p.V110= | Silent (SNP) | VAF 14/447 reads (3%) | called by muse, mutect2
- FER1L6 | c.4179G>A p.R1393= | Silent (SNP) | VAF 30/362 reads (8%) | called by muse, mutect2
- FN1 | c.3093G>A p.V1031= | Silent (SNP) | VAF 111/506 reads (22%) | called by muse, mutect2, varscan2
- FNDC3B | c.2145C>T p.D715= | Silent (SNP) | VAF 133/546 reads (24%) | catalogued as rs1370313563; called by muse, mutect2, varscan2
- FZD7 | c.1179C>T p.T393= | Silent (SNP) | VAF 114/574 reads (20%) | called by muse, mutect2, varscan2
- GATAD2B | c.357A>G p.L119= | Silent (SNP) | VAF 127/499 reads (25%) | catalogued as rs755103378; called by muse, mutect2, varscan2
- GGTLC2 | c.210G>A p.E70= | Silent (SNP) | VAF 81/403 reads (20%) | catalogued as rs1424290114; called by muse, mutect2, varscan2
- GNAS | c.66C>T p.I22= | Silent (SNP) | VAF 36/535 reads (7%) | catalogued as rs757329603; called by muse, mutect2
- GOLGA6L6 | c.1434G>A p.K478= | Silent (SNP) | VAF 135/1632 reads (8%) | called by muse, mutect2
- GPR158 | c.1266C>T p.S422= | Silent (SNP) | VAF 106/417 reads (25%) | catalogued as rs761804192; called by muse, mutect2, varscan2
- GPR37L1 | c.1350G>A p.G450= | Silent (SNP) | VAF 85/450 reads (19%) | called by muse, mutect2, varscan2
- GREB1L | c.903G>A p.G301= | Silent (SNP) | VAF 100/411 reads (24%) | catalogued as rs749894373; called by muse, mutect2, varscan2
- GRIK5 | c.492C>T p.I164= | Silent (SNP) | VAF 78/359 reads (22%) | called by muse, mutect2, varscan2
- GRIN2A | c.987C>T p.V329= | Silent (SNP) | VAF 77/352 reads (22%) | catalogued as COSV58022581; called by muse, mutect2, varscan2
- GRK1 | c.1119G>A p.V373= | Silent (SNP) | VAF 94/434 reads (22%) | catalogued as rs754917668; called by muse, mutect2, varscan2
- GSDME | c.549C>T p.I183= | Silent (SNP) | VAF 61/320 reads (19%) | catalogued as rs367647197; called by muse, mutect2, varscan2
- HACD3 | c.273G>A p.E91= | Silent (SNP) | VAF 32/516 reads (6%) | catalogued as rs893016777; called by muse, mutect2
- HCRTR2 | c.1215G>A p.K405= | Silent (SNP) | VAF 102/469 reads (22%) | called by muse, mutect2, varscan2
- HEATR5B | c.2509T>C p.L837= | Silent (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- HID1 | c.1530G>A p.L510= | Silent (SNP) | VAF 111/483 reads (23%) | called by muse, mutect2, varscan2
- HOXB8 | c.165G>A p.Q55= | Silent (SNP) | VAF 154/646 reads (24%) | called by muse, mutect2, varscan2
- HYDIN | c.11400C>T p.F3800= | Silent (SNP) | VAF 68/361 reads (19%) | catalogued as rs766261324, COSV66641533; called by muse, varscan2
- IGF2BP3 | c.264C>T p.I88= | Silent (SNP) | VAF 36/293 reads (12%) | catalogued as rs759196689; called by muse, mutect2, varscan2
- IGFN1 | c.1806G>A p.G602= (on ENST00000295591 / NM_001367841.1; = p.G3059= on NM_001164586.2) | Silent (SNP) | VAF 133/643 reads (21%) | catalogued as COSV55181863; called by muse, mutect2, varscan2
- IGHV3-30 | c.348G>A p.A116= | Silent (SNP) | VAF 84/1544 reads (5%) | catalogued as rs751676861; called by muse, mutect2
- IGKV1-6 | c.303G>A p.Q101= | Silent (SNP) | VAF 112/525 reads (21%) | called by muse, mutect2, varscan2
- IKZF1 | c.1005G>A p.P335= | Silent (SNP) | VAF 134/550 reads (24%) | catalogued as rs1420799483; called by muse, mutect2, varscan2
- IL3RA | c.288C>T p.F96= | Silent (SNP) | VAF 84/385 reads (22%) | called by muse, mutect2, varscan2
- IPO7 | c.2028C>T p.P676= | Silent (SNP) | VAF 62/345 reads (18%) | called by muse, mutect2, varscan2
- IRAK2 | c.591C>T p.F197= | Silent (SNP) | VAF 16/483 reads (3%) | called by muse, mutect2
- ITGB4 | c.1986G>A p.K662= | Silent (SNP) | VAF 57/266 reads (21%) | called by muse, mutect2, varscan2
- ITLN1 | c.390G>C p.T130= | Silent (SNP) | VAF 94/414 reads (23%) | called by muse, mutect2
- JAKMIP3 | c.54C>T p.L18= | Silent (SNP) | VAF 135/535 reads (25%) | catalogued as rs759673925; called by muse, mutect2, varscan2
- KCNB2 | c.318G>A p.G106= | Silent (SNP) | VAF 104/476 reads (22%) | catalogued as rs1426758995; called by muse, mutect2, varscan2
- KCNC3 | c.1011C>T p.I337= | Silent (SNP) | VAF 137/645 reads (21%) | catalogued as COSV65386593; called by muse, mutect2, varscan2
- KCNH5 | c.885C>T p.I295= | Silent (SNP) | VAF 109/396 reads (28%) | catalogued as rs1230839550, COSV59752184; called by muse, mutect2, varscan2
- KDELR3 | c.507G>A p.R169= | Silent (SNP) | VAF 103/540 reads (19%) | called by muse, varscan2
- KIAA0319 | c.2814G>A p.E938= | Silent (SNP) | VAF 89/381 reads (23%) | catalogued as COSV104427812; called by muse, mutect2, varscan2
- KIF4B | c.99C>T p.S33= | Silent (SNP) | VAF 120/588 reads (20%) | called by muse, mutect2, varscan2
- KLHDC4 | c.807C>T p.F269= | Silent (SNP) | VAF 107/461 reads (23%) | catalogued as COSV54506103; called by muse, mutect2, varscan2
- KLHDC7B | c.1317C>T p.F439= (on ENST00000395676; = p.F1080= on NM_138433.5) | Silent (SNP) | VAF 136/621 reads (22%) | catalogued as COSV67464689; called by muse, mutect2, varscan2
- LAMA5 | c.5841C>T p.S1947= | Silent (SNP) | VAF 121/450 reads (27%) | called by muse, mutect2, varscan2
- LARP1B | c.2527T>C p.L843= | Silent (SNP) | VAF 51/226 reads (23%) | catalogued as rs768588186; called by muse, mutect2, varscan2
- LGALS9B | c.837C>T p.V279= (on ENST00000423676 / NM_001367292.1; = p.V278= on NM_001042685.2) | Silent (SNP) | VAF 31/511 reads (6%) | catalogued as COSV60866105; called by muse, mutect2
- LILRA1 | c.777G>A p.K259= | Silent (SNP) | VAF 122/729 reads (17%) | catalogued as COSV52185350; called by muse, mutect2, varscan2
- LIPM | c.231G>A p.R77= | Silent (SNP) | VAF 77/347 reads (22%) | called by muse, mutect2, varscan2
- LMAN2 | c.951C>T p.P317= | Silent (SNP) | VAF 104/531 reads (20%) | called by muse, mutect2, varscan2
- LOXHD1 | c.5997C>T p.V1999= (on ENST00000642948; = p.V1937= on NM_144612.7) | Silent (SNP) | VAF 115/482 reads (24%) | called by muse, mutect2, varscan2
- LRFN3 | c.537G>A p.L179= | Silent (SNP) | VAF 118/534 reads (22%) | called by muse, mutect2, varscan2
- LRRC18 | c.672C>T p.I224= | Silent (SNP) | VAF 40/658 reads (6%) | catalogued as rs1263756744; called by muse, mutect2
- LRRIQ3 | c.1035G>A p.L345= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as COSV63044081, COSV63044587; called by muse, mutect2, varscan2
- MAD1L1 | c.237G>A p.K79= | Silent (SNP) | VAF 17/591 reads (3%) | called by muse, mutect2
- MAP1A | c.1140G>A p.V380= | Silent (SNP) | VAF 88/361 reads (24%) | catalogued as rs753169421, COSV55814086; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1443C>T p.S481= | Silent (SNP) | VAF 87/373 reads (23%) | catalogued as rs965212258; called by muse, mutect2, varscan2
- MARF1 | c.1419C>T p.V473= | Silent (SNP) | VAF 123/534 reads (23%) | called by muse, mutect2, varscan2
- MARF1 | c.1170C>T p.F390= | Silent (SNP) | VAF 103/464 reads (22%) | catalogued as COSV60027704; called by muse, mutect2, varscan2
- MGAT5B | c.2205C>T p.T735= (on ENST00000569840 / NM_001199172.2; = p.T733= on NM_144677.3) | Silent (SNP) | VAF 63/373 reads (17%) | catalogued as rs373336679; called by muse, mutect2, varscan2
- MKNK2 | c.1182C>T p.S394= | Silent (SNP) | VAF 125/574 reads (22%) | catalogued as rs747371935; called by muse, mutect2, varscan2
- MKRN3 | c.1453T>C p.L485= | Silent (SNP) | VAF 114/362 reads (31%) | called by muse, mutect2, varscan2
- MLH3 | c.2223C>T p.V741= | Silent (SNP) | VAF 62/307 reads (20%) | called by muse, mutect2, varscan2
- MMP17 | c.846C>T p.L282= | Silent (SNP) | VAF 85/452 reads (19%) | called by muse, mutect2, varscan2
- MMP28 | c.471C>T p.A157= | Silent (SNP) | VAF 197/737 reads (27%) | catalogued as rs762267592; called by muse, mutect2, varscan2
- MRTFB | c.633C>T p.S211= | Silent (SNP) | VAF 18/523 reads (3%) | catalogued as COSV57961621; called by muse, mutect2
- MTOR | c.6777C>T p.I2259= | Silent (SNP) | VAF 84/399 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.25431G>A p.A8477= | Silent (SNP) | VAF 125/551 reads (23%) | catalogued as rs779639934, COSV67492521; called by muse, mutect2, varscan2
- MUC16 | c.17898G>A p.R5966= | Silent (SNP) | VAF 107/460 reads (23%) | catalogued as rs1457792064, COSV67483376; called by muse, mutect2, varscan2
- MUC16 | c.6627C>T p.S2209= | Silent (SNP) | VAF 104/391 reads (27%) | called by muse, mutect2, varscan2
- MUC20 | c.639G>A p.E213= | Silent (SNP) | VAF 47/268 reads (18%) | called by muse, mutect2, varscan2
- MYO15A | c.5217G>A p.V1739= | Silent (SNP) | VAF 99/386 reads (26%) | catalogued as COSV52751217; called by muse, mutect2, varscan2
- NANOGNB | c.526C>T p.L176= | Silent (SNP) | VAF 61/298 reads (20%) | called by muse, mutect2
- NCOR2 | c.3174C>T p.P1058= | Silent (SNP) | VAF 155/701 reads (22%) | called by muse, mutect2, varscan2
- NEB | c.16233G>A p.E5411= | Silent (SNP) | VAF 82/340 reads (24%) | called by muse, mutect2, varscan2
- NISCH | c.1167C>T p.I389= | Silent (SNP) | VAF 61/309 reads (20%) | catalogued as rs773478885, COSV61901730; called by muse, mutect2, varscan2
- NLRP3 | c.1440C>T p.I480= | Silent (SNP) | VAF 106/501 reads (21%) | catalogued as COSV60221303; called by muse, mutect2, varscan2
- NLRP3 | c.1441C>T p.L481= | Silent (SNP) | VAF 103/491 reads (21%) | catalogued as rs868633805; called by muse, mutect2, varscan2
- NLRP7 | c.2046G>A p.V682= (on ENST00000340844 / NM_206828.3; = p.V654= on NM_139176.3) | Silent (SNP) | VAF 142/746 reads (19%) | catalogued as rs993360162, COSV60182187; called by muse, mutect2, varscan2
- NPAS2 | c.1824C>T p.T608= | Silent (SNP) | VAF 13/280 reads (5%) | called by muse, mutect2
- NRBF2 | c.189C>T p.S63= | Silent (SNP) | VAF 65/313 reads (21%) | called by muse, mutect2, varscan2
- NRXN2 | c.1245G>A p.Q415= | Silent (SNP) | VAF 94/507 reads (19%) | called by muse, mutect2, varscan2
- NSG2 | c.201C>T p.I67= | Silent (SNP) | VAF 84/363 reads (23%) | catalogued as rs770102568, COSV100292960; called by muse, mutect2, varscan2
- NYAP2 | c.597G>A p.P199= | Silent (SNP) | VAF 124/514 reads (24%) | catalogued as rs529456486, COSV56003344, COSV56006863, COSV56010363; called by muse, mutect2, varscan2
- OLIG1 | c.768C>T p.V256= | Silent (SNP) | VAF 73/329 reads (22%) | catalogued as rs1412217740; called by muse, mutect2, varscan2
- OR2T12 | c.37C>T p.L13= | Silent (SNP) | VAF 20/556 reads (4%) | called by muse, mutect2
- OR4Q3 | c.282C>T p.F94= | Silent (SNP) | VAF 61/428 reads (14%) | catalogued as COSV59177427; called by muse, mutect2, varscan2
- OR56A4 | c.747C>T p.F249= | Silent (SNP) | VAF 96/423 reads (23%) | called by muse, mutect2, varscan2
- OR56A5 | c.591G>A p.L197= | Silent (SNP) | VAF 88/462 reads (19%) | called by muse, mutect2, varscan2
- OR5D18 | c.804C>T p.S268= | Silent (SNP) | VAF 100/510 reads (20%) | catalogued as rs1284733726; called by muse, mutect2
- OR6C1 | c.938G>A p.*313= | Silent (SNP) | VAF 91/235 reads (39%) | catalogued as COSV101110569, COSV65572992; called by muse, mutect2, varscan2
- OR6C2 | c.33C>T p.I11= | Silent (SNP) | VAF 76/380 reads (20%) | catalogued as COSV59516029; called by muse, mutect2, varscan2
- OR6K2 | c.102C>T p.I34= | Silent (SNP) | VAF 135/536 reads (25%) | called by muse, mutect2, varscan2
- PARD6G | c.975G>A p.R325= | Silent (SNP) | VAF 184/757 reads (24%) | catalogued as rs762980156; called by muse, mutect2, varscan2
- PCDHB11 | c.933G>A p.T311= | Silent (SNP) | VAF 108/407 reads (27%) | catalogued as rs782628967, COSV61312143; called by muse, mutect2, varscan2
- PCDHB9 | c.1557G>A p.L519= | Silent (SNP) | VAF 202/861 reads (23%) | called by muse, mutect2, varscan2
- PCNX3 | c.5673C>T p.P1891= | Silent (SNP) | VAF 130/593 reads (22%) | catalogued as rs1265134175; called by muse, mutect2, varscan2
- PHRF1 | c.3615C>T p.P1205= (on ENST00000264555 / NM_001286581.2; = p.P1204= on NM_020901.4) | Silent (SNP) | VAF 169/829 reads (20%) | catalogued as rs1421396635; called by muse, mutect2, varscan2
- PISD | c.123G>A p.L41= | Silent (SNP) | VAF 64/306 reads (21%) | called by muse, mutect2, varscan2
- PKHD1 | c.11040C>T p.S3680= | Silent (SNP) | VAF 84/448 reads (19%) | catalogued as COSV64391529; called by muse, mutect2, varscan2
- PKHD1L1 | c.6868C>T p.L2290= | Silent (SNP) | VAF 61/299 reads (20%) | called by muse, mutect2, varscan2
- PLA2G4E | c.1842G>A p.P614= | Silent (SNP) | VAF 78/256 reads (30%) | catalogued as rs778616263, COSV68150279; called by muse, mutect2, varscan2
- PLAG1 | c.1368C>T p.L456= | Silent (SNP) | VAF 90/357 reads (25%) | catalogued as COSV57609589; called by muse, mutect2, varscan2
- PNPLA6 | c.669C>T p.F223= (on ENST00000414982 / NM_001166111.2; = p.F175= on NM_006702.5) | Silent (SNP) | VAF 145/584 reads (25%) | called by muse, mutect2, varscan2
- POM121L12 | c.777C>T p.P259= | Silent (SNP) | VAF 101/568 reads (18%) | catalogued as rs375344700; called by muse, mutect2, varscan2
- PPRC1 | c.4272C>T p.G1424= | Silent (SNP) | VAF 115/585 reads (20%) | called by muse, mutect2, varscan2
- PRDM9 | c.579G>A p.E193= | Silent (SNP) | VAF 71/424 reads (17%) | catalogued as COSV57014911; called by muse, mutect2, varscan2
- PRKAA2 | c.435C>G p.V145= | Silent (SNP) | VAF 90/421 reads (21%) | catalogued as rs1287351280; called by muse, mutect2, varscan2
- PRKCH | c.1686C>T p.L562= | Silent (SNP) | VAF 99/430 reads (23%) | catalogued as rs769125334; called by muse, mutect2, varscan2
- PTAFR | c.117C>T p.V39= | Silent (SNP) | VAF 92/472 reads (19%) | called by muse, mutect2, varscan2
- PTGES2 | c.972C>T p.F324= | Silent (SNP) | VAF 78/407 reads (19%) | catalogued as COSV99476233; called by muse, mutect2, varscan2
- PTPN3 | c.2412C>T p.L804= | Silent (SNP) | VAF 75/441 reads (17%) | called by muse, mutect2, varscan2
- PTPRO | c.1704C>T p.F568= | Silent (SNP) | VAF 25/620 reads (4%) | called by muse, mutect2
119 further variants in this file (0 protein-altering or splice-affecting, 92 silent, 27 other) are not listed here.
